Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4871, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4871-01A (Primary Tumor).

Pathology Report

DIAGNOSIS

(A) LEFT KIDNEY:

RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR) CELL TYPE, FUHRMAN
NUCLEAR GRADE 4 (12.0 CM).

TUMOR EXTENDING FOCALLY INTO PERIRENAL ADIPOSE TISSUE.

TUMOR INVADING BLOOD VESSEL IN RENAL HILUM. (SEE COMMENT)

Vascular, ureteral, and soft tissue margins of resection free of
tumor.

Adrenal gland, no tumor present.

COMMENT

Grossly no renal vein invasion was identified. In one of the sections
from the tumor in relation to the renal hilar region (parts A7 and A8)
there is tumor invading the lumen and partially the wall of a thick
walled vessel. This is not consider diagnostic of renal vein invasion.

GROSS DESCRIPTION

(A) LEFT KIDNEY - A left radical nephrectomy (24.0 12.5 x 10.5 cm).

Within the upper to mid pole is a partially poorly circumscribed,
heterogenous, hemorrhagic, and necrotic mass (12.0 x 8.5 x 8.0 cm). The
tumor displays multiple focal areas of extension through the renal
capsule into the perirenal adipose tissue. Medially the tumor is seen
at the perirenal soft tissue margin. The mass also extends into the
sinus and also into the renal pelvis. No renal vein invasion is
identified. The uninvolved renal parenchyma appears unremarkable. The
left adrenal gland is present (3.2 x 1.5 x 1.0 cm) and is unremarkable.

A portion of renal parenchyma and tumor is submitted to the Tissue
Bank.

INK CODE: Blue, medial soft tissue margin with tumor.

SECTION CODE: A1, renal vein and ureter margin, en face; A2-A4,
tumor with medial soft tissue margin, perpendicular; A5-A8, tumor in
relation to renal pelvis and sinus; A9, tumor in relation to renal
sinus; A10, tumor in relation to normal kidney; A11, A12 tumor in
relation to periadipose tissue; A13, tumor in relation to normal kidney;
A14, A15, representative sections of more viable appearing tumor; A16,
representative sections of left adrenal gland; A17, A18, representative
sections of normal kidney. [REDACTED]

(B) LEFT 12TH RIB - A portion of rib (8.5 x 1.3 x 0.19 cm). There are
no gross abnormalities. No tissue is submitted for histology. Gross
diagnosis only. [REDACTED]

CLINICAL HISTORY

Left renal mass.

SNOMED CODES

T-71000, M-82123

[REDACTED]

Source: NCI Genomic Data Commons file b59af039-19db-4a46-8702-99d768f62bf7 (TCGA-CJ-4871.E011C8A3-AE9B-41DC-8C14-F98FF2C39951.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).